Surgical pathology report (de-identified scan), TCGA case TCGA-BQ-7061, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BQ-7061-01A (Primary Tumor).

[page 1 of 2]
Patient Name

Med. Rec. #:

DOB:

Gender:

Ref. Physician:

Patient Address:

Ref. Source:

Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

Clinical Diagnosis & History:

Left renal mass.

Specimens Submitted:

1: Left kidney and portion of spleen; total nephrectomy and partial splenectomy

DIAGNOSIS:

1. Left kidney and portion of spleen; total nephrectomy and partial splenectomy:

Tumor Type:

Renal cell carcinoma - Papillary type
Type II

Histologic Grade (for urothelial carcinoma):

High grade

Tumor Size:

Greatest diameter is 4.7 cm.

Local Invasion (for renal cortical types):

Extends through renal capsule but confined within Gerota's fascia

Renal Vein Invasion:

Not identified

Surgical Margins:

Free of tumor

Non-Neoplastic Kidney:

Focal glomerulosclerosis and vascular changes consistent with clinical history of hypertension

Adrenal Gland:

Not identified

Portion of benign congested spleen adherent to kidney, not involved by tumor

Lymph Nodes:

Not identified

Staging for renal cell carcinoma/oncocytoma:

pT1 Tumor <= 7.0 cm in greatest dimension limited to the kidney

Comment: Case reviewed at

[page 2 of 2]
I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

Special Studies:

Result	Special Stain	Comment
	PAS	

Gross Description:

1. The specimen is received fresh labeled "left kidney and portion of spleen" and consists of the aforementioned organs with attached ureter, renal vessels and perinephric fat weighing 272.5 g in total. The kidney measures 10.6 x 5.6 x 4.6 cm. There is a 2.0 x 1.7 x 0.6 cm fragment of grossly unremarkable spleen with a ragged surgical margin (inked blue). The attached ureter measures 4.5 cm in length and 0.3 cm in diameter. The attached renal vein measures 0.9 cm in length and 0.8 cm in diameter. The renal vessels and ureter margins are grossly unremarkable. An adrenal gland is not identified. The kidney is inked black and bivalved to reveal a 4.8 x 4.7 x 4.6 cm lobulated lesion with a tan yellow solid and cystic surface located in the upper pole and midportion of the kidney. This lesions breaks out into perinephric fat and is adherent to the fragment of spleen described above. The tumor approaches within 0.1 of the surgical margins but the margins are grossly negative. Sections through the kidney reveal a pink brown parenchyma, with a poorly-defined cortico-medullary junction. The cortex measures 0.9 cm and the calyces appear normal. Lymph nodes are not identified in the perinephric fat. Representative sections are submitted for TPS and for permanent sections. A gross photograph is taken.

Summary of sections:

UVM -- ureteral and vessel margins
T-- tumor including adherent spleen
THF-- tumor with hilar fat
TSF -- tumor with sinus fat
TK -- tumor with adjacent kidney
RP -- renal pelvis representative sections
K -- representative sections kidney

Summary of Sections:

Part 1: Left kidney and portion of spleen; total nephrectomy and partial splenectomy

Block	Sect. Site	PCs
1	k	1
1	rp	1
5	t	5
2	thf	2
1	tk	1
2	tsf	2
1	uvm	1

Source: NCI Genomic Data Commons file 171605e1-30b8-4dfe-b961-7e6a47df63da (TCGA-BQ-7061.58ECBA8F-5560-42D8-BAF8-F1900E4C8837.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).